Somatic mutation profile of tumor specimen TCGA-CN-5360-01A (aliquot TCGA-CN-5360-01A-01D-1434-08) from TCGA case TCGA-CN-5360, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 68.5 years (25,034 days).
Specimen TCGA-CN-5360-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3e60a7a-c467-450c-b4fc-8b9b2d7add0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-5360-10A (Blood Derived Normal), aliquot TCGA-CN-5360-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c563f29-5007-45b2-b634-69d9b9824ab5

The open-access MAF lists 558 somatic variants for this specimen: 423 protein-altering or splice-affecting, 125 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 364, Silent 125, Nonsense Mutation 26, Frame Shift Del 16, Splice Site 9, Intron 6, Splice Region 3, Frame Shift Ins 3, RNA 3, In Frame Del 1, Translation Start Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.455del p.P152Rfs*18 | Frame Shift Del (DEL) | VAF 11/69 reads (16%) | catalogued as rs730882019, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by mutect2*, pindel, varscan2*
- A1BG | c.761G>A p.R254K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.407); catalogued as COSV99568792; called by muse, mutect2, varscan2
- AASDHPPT | c.886T>C p.C296R | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV99593477; called by muse, mutect2, varscan2
- ABCC9 | c.2340G>A p.R780= | Splice Region (SNP) | VAF 25/134 reads (19%) | catalogued as COSV53973254; called by muse, mutect2, varscan2
- ABCG8 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757824090, COSV99699915; called by muse, mutect2, varscan2
- AC004593.2 | c.1055G>T p.C352F | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99766391; called by muse, mutect2, varscan2
- AC010132.3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.783); catalogued as COSV99786113; called by muse, varscan2
- ACSM2B | c.210G>T p.W70C | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100313266; called by muse, mutect2, varscan2
- ADAMTS12 | c.4548C>G p.H1516Q | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV100711795; called by muse, mutect2, varscan2
- ADAMTS12 | c.2894G>C p.R965P | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100711796, COSV61255980; called by muse, mutect2, varscan2
- ADCY2 | c.1522G>T p.A508S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.394); catalogued as COSV100604597; called by muse, mutect2, varscan2
- ADCY2 | c.3153G>T p.Q1051H | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV100604598; called by muse, mutect2, varscan2
- ADGRB3 | c.1060T>C p.W354R | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV101002099; called by muse, mutect2, varscan2
- ADGRB3 | c.1912G>T p.A638S | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV65407381; called by muse, mutect2, varscan2
- ADGRD1 | c.2327G>A p.G776D | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55452581; called by muse, mutect2, varscan2
- ADGRD1 | c.2396G>T p.G799V | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55457464, COSV99896748; called by muse, mutect2, varscan2
- ADGRV1 | c.2150T>C p.L717S | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.888); catalogued as COSV101316683; called by muse, mutect2, varscan2
- ADPRH | c.619G>T p.V207F | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV100813379; called by muse, mutect2, varscan2
- AGBL1 | c.2756C>G p.T919S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV101224414; called by muse, mutect2, varscan2
- AGMO | c.788A>G p.H263R | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV100694938; called by muse, varscan2
- AKAP9 | c.10991G>C p.G3664A (on ENST00000359028; = p.G3640A on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/261 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV100663356; called by muse, mutect2, varscan2
- AL645922.1 | c.1257G>T p.K419N | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.656); catalogued as COSV100191599; called by muse, mutect2, varscan2
- ALDH1A2 | c.494-1G>T p.X165_splice | Splice Site (SNP) | VAF 38/152 reads (25%) | catalogued as COSV99991204; called by muse, mutect2, varscan2
- ALX4 | c.701A>T p.Q234L | Missense Mutation (SNP) | VAF 91/342 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100241376; called by muse, mutect2, varscan2
- ANKLE1 | c.1124G>A p.W375* (on ENST00000394458; = p.W321* on NM_152363.6) | Nonsense Mutation (SNP) | VAF 35/180 reads (19%) | catalogued as COSV100845795; called by muse, mutect2, varscan2
- ANKRD17 | c.4432G>A p.A1478T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); catalogued as COSV100430141; called by muse, mutect2, varscan2
- AP4E1 | c.550G>T p.V184L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV55919139, COSV99957325; called by muse, mutect2, varscan2
- ARHGAP12 | c.1170G>T p.K390N | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as COSV60961551; called by muse, mutect2
- ARHGEF18 | c.2153G>A p.G718E (on ENST00000359920 / NM_001130955.2; = p.G614E on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100150161; called by muse, mutect2, varscan2
- ASTN1 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV56067848, COSV99923523; called by muse, mutect2, varscan2
- ATP13A3 | c.2881A>C p.S961R | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV99757780; called by muse, mutect2, varscan2
- ATRAID | c.580A>G p.T194A (on ENST00000611786; = p.T81A on NM_016085.5) | Missense Mutation (SNP) | VAF 59/208 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.194); catalogued as COSV99256057; called by muse, mutect2, varscan2
- B3GNTL1 | c.396G>T p.Q132H | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.726); catalogued as COSV100302298; called by muse, varscan2
- BEST3 | c.1156G>T p.G386C | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV100438129; called by muse, mutect2, varscan2
- BICD1 | c.1078G>T p.A360S | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1565673246, COSV99863162; called by muse, mutect2, varscan2
- C2CD3 | c.5546A>T p.N1849I | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100487623; called by muse, mutect2, varscan2
- C2CD5 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as COSV61727273; called by muse, varscan2
- C3orf20 | c.1311C>A p.T437= | Splice Region (SNP) | VAF 18/56 reads (32%) | catalogued as COSV99514720; called by muse, mutect2, varscan2
- C5 | c.2228C>G p.S743C | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as COSV99799016; called by muse, mutect2, varscan2
- C7 | c.2236C>T p.H746Y | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.141); catalogued as rs1187217591, COSV100496768, COSV57473507; called by muse, mutect2, varscan2
- C9 | c.1216G>A p.V406I | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99662699; called by muse, mutect2, varscan2
- C9orf135 | c.153-1G>T p.X51_splice | Splice Site (SNP) | VAF 25/115 reads (22%) | catalogued as COSV101019950; called by muse, mutect2, varscan2
- CABP5 | c.208A>G p.I70V | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV99506781; called by muse, mutect2, varscan2
- CACNA1E | c.4648G>A p.V1550M | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773509097, COSV100705928; called by muse, mutect2, varscan2
- CACNG6 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 129/498 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs777776975, COSV53166275, COSV99079068; called by muse, mutect2, varscan2
- CARNMT1 | c.1037A>T p.Y346F | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV100961825; called by muse, mutect2, varscan2
- CASP5 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); catalogued as COSV99508225; called by muse, mutect2
- CCNT2 | c.1404del p.Q469Sfs*16 | Frame Shift Del (DEL) | VAF 11/82 reads (13%) | catalogued as COSV99751341; called by mutect2, pindel, varscan2
- CCP110 | c.2787A>C p.E929D | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); catalogued as COSV101195360; called by muse, mutect2, varscan2
- CDH17 | c.817T>G p.L273V | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as COSV99218196; called by muse, mutect2, varscan2
- CDKN2A | c.134del p.G45Vfs*8 | Frame Shift Del (DEL) | VAF 45/131 reads (34%) | catalogued as COSV58685320; called by mutect2, pindel, varscan2
- CDR1 | c.118C>A p.L40M | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); catalogued as COSV100983471; called by muse, mutect2, varscan2
- CEACAM18 | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as COSV101140790; called by muse, mutect2, varscan2
- CEACAM5 | c.179A>T p.Q60L | Missense Mutation (SNP) | VAF 59/243 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.885); catalogued as COSV99704223; called by muse, mutect2, varscan2
- CEMIP2 | c.500A>G p.D167G | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as rs762057376, COSV100987559; called by muse, mutect2, varscan2
- CENPE | c.5498T>C p.I1833T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs985322347, COSV99479510; called by muse, mutect2, varscan2
- CEP170 | c.1162A>T p.R388W | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100318083; called by muse, mutect2, varscan2
- CFAP47 | c.2118G>T p.R706S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as COSV99934622; called by muse, mutect2, varscan2
- CHD8 | c.6985G>A p.E2329K (on ENST00000646647 / NM_001170629.2; = p.E2050K on NM_020920.4) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV100765391; called by muse, mutect2, varscan2
- CHST13 | c.122C>A p.S41Y | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV100081437, COSV60043494; called by muse, mutect2, varscan2
- CNTNAP5 | c.1634G>A p.S545N | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.162); catalogued as rs367937965; called by muse, mutect2, varscan2
- COL3A1 | c.2932G>T p.G978C | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM066013, COSV58593753; called by muse, mutect2, varscan2
- COL8A1 | c.151T>C p.Y51H | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as rs1255426310, COSV99658678; called by muse, mutect2, varscan2
- CPLX4 | c.158T>C p.I53T | Missense Mutation (SNP) | VAF 61/231 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as COSV100231578, COSV55314406; called by muse, mutect2, varscan2
- CPT1B | c.1751A>C p.K584T | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV56416138; called by muse, mutect2, varscan2
- CPTP | c.586C>A p.R196S | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV100028750; called by muse, mutect2, varscan2
- CSMD3 | c.9341G>T p.C3114F (on ENST00000297405 / NM_001363185.1; = p.C2945F on NM_052900.3) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99851560; called by muse, mutect2, varscan2
- CTNNA2 | c.175G>T p.V59L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs755217215, COSV100786694; called by muse, mutect2, varscan2
- CTNNA2 | c.2201C>A p.P734Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100562386; called by muse, mutect2, varscan2
- CTSS | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1299317068, COSV100935053; called by muse, mutect2, varscan2
- CUL3 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.527); catalogued as COSV100024991; called by muse, mutect2, varscan2
- CUX1 | c.4483G>A p.A1495T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs782663588, COSV99473516; called by muse, varscan2
- DACH2 | c.1573del p.T525Pfs*33 | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | catalogued as COSV100912973, COSV64169192; called by mutect2, pindel, varscan2
- DACT1 | c.1344G>C p.Q448H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.787); catalogued as COSV60022502; called by muse, mutect2, varscan2
- DCSTAMP | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs755037579, COSV52577542; called by muse, mutect2, varscan2
- DHX37 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs529499939, COSV100439602; called by muse, mutect2, varscan2
- DLX5 | c.595G>T p.G199W | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99756472; called by muse, mutect2, varscan2
- DMP1 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs914350381, COSV99219094; called by muse, mutect2, varscan2
- DNAAF3 | c.10C>A p.P4T (on ENST00000524407 / NM_001256715.2; = p.P51T on NM_178837.4) | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.526); catalogued as COSV100845970, COSV62830456; called by muse, varscan2
- DNAH12 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.708); catalogued as rs775094423, COSV100244926; called by muse, mutect2, varscan2
- DNAH3 | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs1031170976, COSV54529855; called by muse, mutect2, varscan2
- DNAH5 | c.3379A>T p.I1127F | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV99455555; called by muse, mutect2, varscan2
- DNAH9 | c.11968A>T p.M3990L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV99308831; called by muse, mutect2, varscan2
- DNAJC10 | c.659G>T p.R220I | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99899696; called by muse, mutect2, varscan2
- DOCK3 | c.1304G>T p.R435I | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56515600, COSV56540639, COSV99815927; called by muse, mutect2, varscan2
- DPP6 | c.2417A>G p.Q806R (on ENST00000377770 / NM_001364500.2; = p.Q744R on NM_001936.5) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.305); catalogued as COSV100128866; called by muse, mutect2, varscan2
- DPPA4 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV100169791; called by muse, mutect2, varscan2
- DPY19L3 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs143875213; called by muse, mutect2, varscan2
- DST | c.7513G>T p.V2505L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.006); catalogued as COSV55008729, COSV99761051; called by muse, mutect2, varscan2
- DZANK1 | c.1549A>T p.T517S (on ENST00000262547 / NM_001099407.1; = p.T324S on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/162 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV99363559; called by muse, mutect2, varscan2
- ENPP7 | c.775C>A p.L259M | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.951); catalogued as COSV100093801; called by muse, mutect2, varscan2
- ENTHD1 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as COSV57317686; called by muse, mutect2, varscan2
- EPHB1 | c.943C>A p.P315T | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV101212478; called by muse, mutect2, varscan2
- F5 | c.808C>T p.H270Y | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100889293; called by muse, mutect2, varscan2
- FBN1 | c.7546A>T p.T2516S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV100356644; called by muse, mutect2, varscan2
- FCRL1 | c.132G>T p.Q44H | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV100839926; called by muse, mutect2, varscan2
- FCRL2 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs200209730, COSV100830032; called by muse, mutect2, varscan2
- FCRL4 | c.846G>T p.Q282H | Missense Mutation (SNP) | VAF 76/345 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.465); catalogued as COSV99620631; called by muse, varscan2
- FGF23 | c.617G>T p.C206F | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.88); catalogued as COSV99426790; called by muse, mutect2, varscan2
- FN1 | c.4217T>G p.V1406G | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100118548; called by muse, mutect2, varscan2
- FOXA1 | c.73-1G>C p.X25_splice | Splice Site (SNP) | VAF 13/78 reads (17%) | catalogued as COSV99164036; called by muse, mutect2, varscan2
- FOXI1 | c.1115C>A p.P372H | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.635); catalogued as COSV100089663, COSV60389865; called by muse, mutect2, varscan2
- FREM1 | c.2839G>C p.D947H | Missense Mutation (SNP) | VAF 73/224 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV101085723, COSV66517749, COSV66518799; called by muse, mutect2, varscan2
- FRG2B | c.659A>G p.Q220R | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as COSV101423551; called by muse, mutect2, varscan2
- GABRB3 | c.1226G>T p.R409L | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV54658144, COSV54689839; called by muse, mutect2, varscan2
- GABRR1 | c.1276C>A p.Q426K | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.216); catalogued as rs549063825, COSV101034199; called by muse, mutect2, varscan2
- GALNT13 | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 49/217 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101223257, COSV101224409; called by muse, mutect2, varscan2
- GALNT13 | c.1144A>T p.I382F | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV101224410; called by muse, mutect2, varscan2
- GALNT3 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV67061422; called by muse, mutect2, varscan2
- GALNTL6 | c.419C>A p.P140Q | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101487916; called by muse, mutect2, varscan2
- GALR1 | c.290C>A p.A97E | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV100232143; called by muse, mutect2, varscan2
- GAREM1 | c.1997C>T p.P666L (on ENST00000269209 / NM_001242409.2; = p.P665L on NM_022751.3) | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV99331581; called by muse, mutect2, varscan2
- GAS2L3 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV99903239; called by muse, mutect2, varscan2
- GNG2 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 59/250 reads (24%) | catalogued as COSV100088092; called by muse, mutect2, varscan2
- GOLGA1 | c.1030A>G p.S344G | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.396); catalogued as COSV101001998; called by muse, mutect2, varscan2
- GOLGB1 | c.5600A>C p.E1867A | Missense Mutation (SNP) | VAF 88/433 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.371); catalogued as COSV100511677; called by muse, mutect2, varscan2
- GPC5 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV100996359; called by muse, mutect2, varscan2
- GPR108 | c.380A>G p.Q127R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs550205099, COSV99901614; called by muse, mutect2, varscan2
- GREB1 | c.757G>T p.G253* | Nonsense Mutation (SNP) | VAF 23/89 reads (26%) | catalogued as COSV99304043; called by muse, mutect2, varscan2
- GRIN2B | c.2854C>A p.P952T | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.239); catalogued as COSV101663229; called by muse, mutect2, varscan2
- GTF3C1 | c.382A>G p.R128G | Missense Mutation (SNP) | VAF 77/276 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV99852255; called by muse, mutect2, varscan2
- GYS2 | c.721C>G p.R241G | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99680368; called by muse, mutect2, varscan2
- H2AC12 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV100804784; called by muse, mutect2, varscan2
- H2BC18 | c.248A>T p.H83L | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV100516207; called by muse, mutect2, varscan2
- HAP1 | c.1949A>G p.K650R (on ENST00000310778 / NM_001367460.1; = p.K598R on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/276 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV100170116; called by muse, mutect2, varscan2
- HERC2 | c.11506A>T p.R3836W | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99877618; called by muse, mutect2, varscan2
- HK3 | c.2147G>A p.G716D | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1359834303, COSV99459648; called by muse, mutect2, varscan2
- HORMAD1 | c.96G>T p.R32S | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100464556; called by muse, mutect2, varscan2
- HTR1E | c.807C>A p.D269E | Missense Mutation (SNP) | VAF 72/302 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59508260; called by muse, mutect2
- IGF1R | c.1707T>A p.H569Q | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99163584; called by muse, mutect2, varscan2
- IGF1R | c.1708G>T p.G570W | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.825); catalogued as COSV99163590; called by muse, mutect2, varscan2
- IGSF21 | c.939C>G p.I313M | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as rs371464766, COSV52125736; called by muse, mutect2, varscan2
- IL12RB1 | c.990G>T p.Q330H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV100443250; called by muse, mutect2
- IL1RL1 | c.158C>G p.T53R | Missense Mutation (SNP) | VAF 56/301 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99294648; called by muse, mutect2, varscan2
- IL7R | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV100286773, COSV99073422; called by muse, mutect2, varscan2
- IMPG1 | c.971C>A p.S324Y | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100885887, COSV100886779; called by muse, mutect2, varscan2
- INSR | c.3632G>T p.G1211V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100253835; called by muse, mutect2, varscan2
- INTS6L | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0.402); catalogued as COSV100878001, COSV66086702; called by muse, mutect2, varscan2
- IQGAP2 | c.1430T>C p.L477P | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.836); catalogued as COSV99169303; called by muse, mutect2, varscan2
- IQUB | c.1758G>T p.K586N | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100227441; called by muse, mutect2, varscan2
- IQUB | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 25/179 reads (14%) | catalogued as COSV100227442; called by muse, mutect2, varscan2
- IREB2 | c.1771G>T p.A591S | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.352); catalogued as rs746547492, COSV51921941, COSV99359826; called by muse, mutect2, varscan2
- IRX5 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs377035980; called by muse, mutect2, varscan2
- ITGA8 | c.1705C>A p.P569T | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT tolerated (0.98); PolyPhen benign (0.124); catalogued as COSV100959904, COSV65236355; called by muse, mutect2, varscan2
- JAK3 | c.1520A>T p.Q507L | Missense Mutation (SNP) | VAF 98/316 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV71686693, COSV99070385; called by muse, mutect2, varscan2
- KCNH6 | c.2905C>A p.H969N | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.013); catalogued as COSV59005053; called by muse, mutect2, varscan2
- KCNK1 | c.676A>G p.I226V | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs753081999, COSV100785811; called by muse, mutect2, varscan2
- KDR | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 80/163 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.438); catalogued as rs760248367, COSV99818936; called by muse, mutect2, varscan2
- KIAA0586 | c.1979G>T p.R660I (on ENST00000619416 / NM_001244190.2; = p.R599I on NM_014749.5) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV99709191; called by muse, mutect2, varscan2
- KIAA1549 | c.498G>T p.W166C | Missense Mutation (SNP) | VAF 167/353 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99652344; called by muse, mutect2, varscan2
- KIF13B | c.970A>T p.T324S | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101580890; called by muse, mutect2, varscan2
- KIF6 | c.1845A>G p.I615M | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs375315494; called by muse, mutect2, varscan2
- KLF14 | c.511C>G p.L171V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100206011; called by muse, mutect2
- KMT2B | c.3981G>T p.R1327S | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV99720875; called by muse, mutect2, varscan2
- KMT2C | c.5600G>C p.S1867T | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100078053; called by muse, mutect2, varscan2
- KRBA1 | c.853A>T p.R285W | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99753230; called by muse, mutect2, varscan2
- KRT12 | c.487A>T p.T163S | Missense Mutation (SNP) | VAF 58/283 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99289202; called by muse, mutect2, varscan2
- L3MBTL3 | c.817G>T p.V273L | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.145); catalogued as rs766315177, COSV100695823, COSV100696473; called by muse, mutect2
- L3MBTL3 | c.1220A>G p.N407S | Missense Mutation (SNP) | VAF 73/334 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as COSV100696474; called by muse, mutect2, varscan2
- LAMA1 | c.342A>T p.R114S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as COSV101058031; called by muse, mutect2, varscan2
- LAMA2 | c.188C>A p.P63H | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101370946; called by muse, mutect2, varscan2
- LITAF | c.85G>T p.V29F | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100243272; called by muse, mutect2, varscan2
- LRFN1 | c.1733G>T p.R578L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99953486; called by muse, mutect2, varscan2
- LRFN5 | c.359G>A p.S120N | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.179); catalogued as rs1410518198, COSV99985859; called by muse, mutect2, varscan2
- LRP1 | c.4400G>A p.G1467D | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV99677774; called by muse, mutect2, varscan2
- LRP1B | c.6030G>T p.L2010F | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs776979327, COSV67234661; called by muse, mutect2, varscan2
- LRRC4C | c.1116G>T p.E372D | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as COSV99540236; called by muse, mutect2, varscan2
- LYSMD4 | c.511A>T p.K171* (on ENST00000409796 / NM_001284417.2; = p.K172* on NM_152449.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 40/146 reads (27%) | catalogued as COSV100230763; called by muse, mutect2, varscan2
- MAGEB3 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV100854842, COSV64397818; called by muse, mutect2, varscan2
- MAGEB3 | c.905C>G p.A302G | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100854843, COSV64396767; called by muse, mutect2, varscan2
- MAGEC1 | c.2302G>C p.E768Q | Missense Mutation (SNP) | VAF 107/241 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as COSV99596826; called by muse, mutect2, varscan2
- MAGEC1 | c.2453C>A p.P818H | Missense Mutation (SNP) | VAF 115/248 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.511); catalogued as COSV53579841, COSV99596828; called by muse, mutect2, varscan2
- MAGEE2 | c.486C>A p.F162L | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100973250, COSV64897833; called by muse, mutect2, varscan2
- MAP2K6 | c.367G>T p.G123C | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100765155; called by muse, mutect2, varscan2
- MBD5 | c.974G>T p.R325L | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV101290297; called by muse, mutect2, varscan2
- MCC | c.1947G>T p.K649N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100203301; called by muse, mutect2, varscan2
- MDN1 | c.13120C>T p.R4374W | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs753798288, COSV65521583; called by muse, mutect2, varscan2
- MDN1 | c.10377G>T p.L3459F | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101021941; called by muse, varscan2
- MED12 | c.622G>T p.G208W | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.571); catalogued as COSV100375808; called by muse, mutect2, varscan2
- MED12L | c.2162A>T p.H721L | Missense Mutation (SNP) | VAF 112/765 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV99855181; called by muse, mutect2, varscan2
- MED13 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV101181533, COSV67262127; called by muse, mutect2, varscan2
- MFSD5 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100289195; called by muse, mutect2, varscan2
- MFSD6L | c.129G>T p.L43F | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100267016; called by muse, mutect2, varscan2
- MGAM | c.3278G>T p.G1093V | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101527796; called by muse, mutect2, varscan2
- MGAM | c.4936G>A p.V1646M | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV101527449, COSV101527797; called by muse, mutect2, varscan2
- MME | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 30/277 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV100852578; called by muse, mutect2, varscan2
- MNDA | c.813C>A p.Y271* | Nonsense Mutation (SNP) | VAF 14/83 reads (17%) | catalogued as COSV100933479; called by muse, mutect2, varscan2
- MORC1 | c.155-2A>T p.X52_splice | Splice Site (SNP) | VAF 50/192 reads (26%) | catalogued as COSV99228184; called by muse, mutect2, varscan2
- MPPE1 | c.558G>A p.W186* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100013462; called by muse, mutect2, varscan2
- MROH2B | c.4396C>T p.Q1466* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | catalogued as COSV101270969; called by muse, mutect2, varscan2
- MROH9 | c.112C>A p.L38M | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV100883128; called by muse, varscan2
- MRRF | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.065); catalogued as COSV99939090; called by muse, mutect2, varscan2
- MUC16 | c.6209C>T p.S2070F | Missense Mutation (SNP) | VAF 70/246 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV101202186; called by muse, mutect2, varscan2
- MUC16 | c.2900G>A p.W967* | Nonsense Mutation (SNP) | VAF 67/321 reads (21%) | catalogued as COSV101202187; called by muse, mutect2, varscan2
- MYCBP2 | c.12928C>G p.P4310A (on ENST00000357337; = p.P4348A on NM_015057.5) | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV100632443; called by muse, mutect2, varscan2
- MYH1 | c.4111G>A p.E1371K | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1203608310, COSV99877197; called by muse, mutect2, varscan2
- MYH2 | c.5002C>T p.R1668W | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs569489518, COSV55431886, COSV55435762; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH2 | c.4222G>A p.E1408K | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs780588979, COSV55449788; called by muse, mutect2, varscan2
- MYO16 | c.846C>A p.H282Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV99194967; called by muse, mutect2, varscan2
- MYO18B | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); catalogued as rs757431703, COSV100125611; called by muse, mutect2, varscan2
- MYO1G | c.2476C>T p.R826C | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1201850845, COSV51855596; called by muse, mutect2, varscan2
- MYO6 | c.3703G>T p.E1235* (on ENST00000369981; = p.E1225* on NM_004999.4) | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV100889445; called by muse, mutect2, varscan2
- MYOCD | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 77/232 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1394360964, COSV58497819; called by muse, mutect2, varscan2
- MYOG | c.430C>G p.R144G | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99614171; called by muse, mutect2, varscan2
- NAA25 | c.1658T>C p.L553P | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99928176; called by muse, mutect2, varscan2
- NAMPT | c.606G>T p.E202D | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99748395; called by muse, mutect2, varscan2
- NAV3 | c.2144C>A p.T715K | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99896848; called by muse, mutect2, varscan2
- NAV3 | c.2446G>C p.D816H | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV99896853; called by muse, mutect2, varscan2
- NAV3 | c.2872G>T p.G958C | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV99896857; called by muse, mutect2, varscan2
- NAV3 | c.4968C>A p.D1656E | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.205); catalogued as COSV57078866; called by muse, mutect2, varscan2
- NCBP2L | c.235T>C p.C79R | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772696296, COSV100966535; called by muse, mutect2, varscan2
- NEK10 | c.2684A>G p.E895G | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV55354409, COSV99835786; called by muse, mutect2, varscan2
- NEK10 | c.2390C>G p.S797C | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.119); catalogued as COSV99835788; called by muse, mutect2, varscan2
- NEUROD1 | c.265A>C p.K89Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV99717094; called by muse, mutect2, varscan2
- NEUROD6 | c.464G>A p.R155K | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.745); catalogued as rs1214094568, COSV99774245; called by muse, mutect2, varscan2
- NFXL1 | c.2093G>A p.C698Y | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100217136; called by muse, mutect2
- NID2 | c.1387T>C p.Y463H | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV53497036; called by muse, mutect2, varscan2
- NMS | c.415C>A p.P139T | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV100966691; called by muse, mutect2, varscan2
- NOSIP | c.85G>T p.G29W | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.35); catalogued as COSV100182531; called by muse, mutect2, varscan2
- NPAP1 | c.736G>C p.A246P | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100276375; called by muse, mutect2, varscan2
- NPAP1 | c.1571C>G p.P524R | Missense Mutation (SNP) | VAF 76/387 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV100276376, COSV61505780; called by muse, mutect2, varscan2
- NRXN3 | c.1453C>A p.L485I (on ENST00000335750 / NM_001330195.2; = p.L112I on NM_004796.6) | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV100210740; called by muse, mutect2, varscan2
- NSD1 | c.2231C>G p.S744* | Nonsense Mutation (SNP) | VAF 26/86 reads (30%) | catalogued as COSV100729932; called by muse, mutect2, varscan2
- OGDHL | c.1203T>G p.F401L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV100934581; called by muse, mutect2, varscan2
- OPRPN | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 27/103 reads (26%) | catalogued as COSV101271113; called by muse, mutect2, varscan2
- OR10G8 | c.458T>A p.L153Q | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101461899; called by muse, mutect2, varscan2
- OR10S1 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV101602515; called by muse, mutect2, varscan2
- OR13C5 | c.740T>G p.V247G | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101053198; called by muse, mutect2, varscan2
- OR2AG2 | c.624G>T p.L208F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV58455347, COSV58456407; called by muse, mutect2, varscan2
- OR2C3 | c.485C>A p.T162K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs562326145, COSV63574257, COSV63574402, COSV63574958; called by mutect2, varscan2
- OR2M5 | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 301/798 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV100822900; called by muse, mutect2, varscan2
- OR2W1 | c.160C>A p.Q54K | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs757055317, COSV101013955; called by muse, mutect2, varscan2
- OR4A5 | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV100157369; called by muse, mutect2
- OR5AR1 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV100265584; called by muse, mutect2, varscan2
- OR5D18 | c.865C>A p.L289M | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV100450954, COSV61737830; called by muse, mutect2
- OR5H15 | c.199G>C p.A67P | Missense Mutation (SNP) | VAF 75/462 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100736801; called by muse, mutect2, varscan2
- OR5M3 | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56567352; called by muse, mutect2, varscan2
- OR8G1 | c.142C>A p.L48M | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV100422720; called by muse, mutect2
- OR9G4 | c.268A>G p.K90E | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV100265296; called by muse, mutect2
- OR9K2 | c.271C>A p.L91I (on ENST00000305377; = p.L69I on NM_001005243.1) | Missense Mutation (SNP) | VAF 74/371 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59531536; called by muse, mutect2, varscan2
- OXTR | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV100373369; called by muse, varscan2
- PAM | c.841G>T p.G281C | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs779890802, COSV99173983; called by muse, mutect2, varscan2
- PAPPA | c.1427C>G p.P476R | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100075717, COSV60291715; called by muse, mutect2, varscan2
- PAPPA2 | c.666G>T p.W222C | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.253); catalogued as COSV100867271; called by muse, mutect2, varscan2
- PARP2 | c.387C>A p.N129K | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99163116; called by muse, varscan2
- PCDH11X | c.3010C>T p.P1004S | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV100016227; called by muse, mutect2, varscan2
- PCDHA10 | c.667G>T p.G223* | Nonsense Mutation (SNP) | VAF 65/188 reads (35%) | catalogued as rs1233191211, COSV100255850, COSV56480508; called by muse, mutect2, varscan2
- PCDHA3 | c.333C>A p.D111E | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.011); catalogued as COSV100974196, COSV65366760; called by muse, mutect2, varscan2
- PCDHA7 | c.1438G>T p.G480W | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV65342702; called by muse, mutect2, varscan2
- PCDHB10 | c.1004T>A p.V335E | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as COSV99505190; called by muse, mutect2, varscan2
- PCDHB7 | c.1551G>T p.R517S | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.201); catalogued as COSV99177590; called by muse, mutect2, varscan2
- PDZD2 | c.7156G>A p.G2386S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs867133896, COSV99227227; called by muse, mutect2, varscan2
- PEG3 | c.4270G>C p.G1424R | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); catalogued as COSV99690876; called by muse, mutect2, varscan2
- PHOX2A | c.835C>A p.L279M | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.421); catalogued as COSV99996770; called by muse, mutect2, varscan2
- PIK3CA | c.2911T>C p.C971R | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.084); catalogued as COSV55954864; called by muse, mutect2, varscan2
- PJA1 | c.975A>T p.K325N (on ENST00000361478 / NM_145119.4; = p.K137N on NM_022368.5) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV100824849; called by muse, mutect2, varscan2
- PKDREJ | c.2389C>A p.R797S | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99479671; called by muse, mutect2, varscan2
- PKHD1 | c.1049A>T p.Y350F | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100584951; called by muse, mutect2, varscan2
- PLAG1 | c.671G>C p.R224P | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100388330, COSV57610798, COSV57613013; called by muse, mutect2, varscan2
- PLOD2 | c.1287G>T p.W429C | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51469536; called by muse, mutect2, varscan2
- PLXNA2 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100886157; called by muse, mutect2, varscan2
- PNLIPRP2 | c.89A>T p.D30V | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV100078041; called by muse, mutect2, varscan2
- PNN | c.113G>T p.R38M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99397461; called by muse, mutect2
- POLE | c.2469-2A>T p.X823_splice | Splice Site (SNP) | VAF 17/58 reads (29%) | catalogued as COSV100268693; called by muse, mutect2, varscan2
- POLR3B | c.836C>T p.T279I | Missense Mutation (SNP) | VAF 79/292 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99943979; called by muse, mutect2, varscan2
- PON1 | c.850T>A p.C284S | Missense Mutation (SNP) | VAF 61/123 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV99732691; called by muse, mutect2, varscan2
- POTEH | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.145); catalogued as COSV100625320, COSV58885723; called by muse, mutect2, varscan2
- POTEH | c.295G>C p.G99R | Missense Mutation (SNP) | VAF 67/456 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100625318, COSV58879462, COSV58882978; called by muse, varscan2
- PPIP5K2 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV100384373; called by muse, mutect2, varscan2
- PPP1R11 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.347); catalogued as COSV99748807; called by muse, mutect2, varscan2
- PRDM5 | c.118G>T p.G40* | Nonsense Mutation (SNP) | VAF 52/189 reads (28%) | catalogued as COSV99311656; called by muse, mutect2, varscan2
- PRDM9 | c.1112G>T p.S371I | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV99691513; called by muse, mutect2, varscan2
- PRKCG | c.1538G>T p.R513L | Missense Mutation (SNP) | VAF 94/562 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.436); catalogued as COSV54724103, COSV99669684; called by muse, mutect2, varscan2
- PTCHD4 | c.2294C>A p.S765Y | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV100261961; called by muse, mutect2, varscan2
- PTPRC | c.1994G>T p.S665I | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100723326; called by muse, mutect2, varscan2
- RAB34 | c.605-2A>T p.X202_splice | Splice Site (SNP) | VAF 14/74 reads (19%) | catalogued as COSV99973215; called by muse, mutect2, varscan2
- RBBP6 | c.3734A>C p.E1245A | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.453); catalogued as COSV100155140; called by muse, mutect2, varscan2
- RBP4 | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761838369, COSV101012311; called by muse, varscan2
- RBPJL | c.746C>A p.T249K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100643572, COSV59212762; called by muse, mutect2, varscan2
- RCOR1 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as rs992292547, COSV99217872; called by muse, mutect2, varscan2
- RDH8 | c.343C>A p.L115M (on ENST00000651512; = p.L95M on NM_015725.4) | Missense Mutation (SNP) | VAF 53/327 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as COSV99408849; called by muse, mutect2, varscan2
- RFX6 | c.614A>T p.H205L | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100264446; called by muse, mutect2, varscan2
- RGS6 | c.927G>T p.W309C | Missense Mutation (SNP) | VAF 90/312 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100667271; called by muse, mutect2, varscan2
- RGS7 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 78/322 reads (24%) | catalogued as COSV100471887, COSV58541016; called by muse, mutect2, varscan2
- RHBDF2 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV100489742; called by muse, mutect2, varscan2
- RHOT2 | c.631G>C p.A211P | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.334); catalogued as COSV99554332; called by muse, mutect2, varscan2
- RIMS2 | c.1027C>T p.P343S (on ENST00000666250 / NM_001348490.2; = p.P151S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99212632; called by muse, mutect2, varscan2
- RIPOR2 | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99430424; called by muse, mutect2, varscan2
- ROBO4 | c.1620C>G p.S540R | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100127921; called by muse, mutect2, varscan2
- RP1 | c.6133G>T p.G2045C | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as COSV99609221; called by muse, mutect2, varscan2
- RSPH10B2 | c.2468A>G p.K823R | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs773831227, COSV99786466; called by muse, mutect2, varscan2
- RTL10 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs895536422, COSV100144317; called by muse, mutect2, varscan2
- RTTN | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99734127; called by muse, mutect2, varscan2
- SAMD3 | c.195G>C p.Q65H | Missense Mutation (SNP) | VAF 67/279 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.754); catalogued as COSV100148478; called by muse, mutect2, varscan2
- SAMD7 | c.197G>A p.S66N | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100157135; called by muse, mutect2, varscan2
- SARDH | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.102); catalogued as COSV53833504; called by muse, mutect2, varscan2
- SARDH | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.319); catalogued as COSV100061397; called by muse, mutect2, varscan2
- SCGN | c.308C>A p.P103Q | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.233); catalogued as COSV100618894; called by muse, mutect2, varscan2
- SCN2A | c.2167C>G p.Q723E | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99333987; called by muse, mutect2, varscan2
- SCN3A | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99328949; called by muse, mutect2, varscan2
- SEL1L2 | c.657G>T p.M219I | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1329308050, COSV99534146; called by muse, mutect2, varscan2
- SESTD1 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as rs1362383512, COSV100091005, COSV58931401; called by muse, mutect2, varscan2
- SFMBT1 | c.145G>T p.G49* | Nonsense Mutation (SNP) | VAF 35/127 reads (28%) | catalogued as COSV99966522; called by muse, mutect2, varscan2
- SI | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV52269684; called by muse, mutect2, varscan2
- SIGIRR | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.154); catalogued as COSV100230382; called by muse, mutect2, varscan2
- SLC12A8 | c.2108C>A p.S703Y | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV100103118, COSV100103282; called by muse, mutect2
- SLC2A4 | c.1040C>A p.A347E | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99142861; called by muse, mutect2, varscan2
- SLC35A5 | c.815A>G p.Y272C | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760151598, COSV99656939; called by muse, mutect2, varscan2
- SLC39A12 | c.18G>T p.K6N | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV101070217; called by muse, mutect2, varscan2
- SLC40A1 | c.760+1G>T p.X254_splice | Splice Site (SNP) | VAF 25/80 reads (31%) | catalogued as COSV99656602; called by muse, varscan2
- SLC6A11 | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.6); catalogued as COSV99595167; called by muse, mutect2, varscan2
- SLC9C1 | c.3512T>A p.L1171Q | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); catalogued as COSV99998999; called by muse, varscan2
- SLITRK3 | c.1984G>T p.V662F | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs1178396440, COSV99580391; called by muse, mutect2, varscan2
- SLITRK4 | c.2459G>T p.S820I | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100567583; called by muse, mutect2, varscan2
- SLITRK4 | c.1080C>A p.N360K | Missense Mutation (SNP) | VAF 74/142 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100567584; called by muse, mutect2, varscan2
- SLTM | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); catalogued as COSV51055518; called by muse, mutect2, varscan2
- SMIM21 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.003); catalogued as rs375362339, COSV66894840; called by muse, mutect2, varscan2
- SMOC2 | c.1313C>T p.S438F (on ENST00000356284 / NM_001166412.2; = p.S449F on NM_022138.3) | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); catalogued as COSV100635762; called by muse, mutect2, varscan2
- SMPDL3B | c.1061G>T p.R354L | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV100874623; called by muse, mutect2, varscan2
- SOGA3 | c.2269G>A p.A757T | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.087); catalogued as COSV64105879; called by muse, mutect2, varscan2
- SOX4 | c.1301T>G p.F434C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99782231; called by muse, mutect2, varscan2
- SPANXN1 | c.165C>A p.C55* | Nonsense Mutation (SNP) | VAF 39/71 reads (55%) | catalogued as rs782601684, COSV100979463, COSV65122993; called by muse, mutect2, varscan2
- SPATA18 | c.38C>G p.T13S | Missense Mutation (SNP) | VAF 43/297 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54650500; called by muse, mutect2, varscan2
- SPATA31D1 | c.3611T>C p.M1204T | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV100783144; called by muse, mutect2, varscan2
- SPATA31D1 | c.4628C>G p.P1543R | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.555); catalogued as COSV61200157; called by muse, mutect2
- SPHKAP | c.3193C>A p.P1065T | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV60882570, COSV60896018; called by muse, mutect2, varscan2
- SPSB1 | c.443G>T p.R148L | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV100049722; called by muse, mutect2, varscan2
- SPTA1 | c.2174G>T p.R725L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375230030, COSV100935788; called by muse, mutect2, varscan2
- SPTBN1 | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100777439; called by muse, mutect2, varscan2
- STAB2 | c.1240G>T p.G414* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV101186466; called by muse, mutect2, varscan2
- STAB2 | c.4398del p.T1467Pfs*94 | Frame Shift Del (DEL) | VAF 32/132 reads (24%) | catalogued as COSV66348545; called by mutect2, pindel, varscan2
- STK35 | c.1169G>T p.G390V | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV99853136; called by muse, mutect2, varscan2
- STXBP5 | c.2122G>A p.D708N | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); catalogued as COSV99471185; called by muse, mutect2, varscan2
- STYXL2 | c.2281A>G p.S761G | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99610061; called by muse, mutect2, varscan2
- SYNE1 | c.8270A>T p.E2757V (on ENST00000367255 / NM_182961.4; = p.E2764V on NM_033071.3) | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.115); catalogued as COSV99583977; called by muse, mutect2, varscan2
- TAAR1 | c.823C>A p.P275T | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs752052018, COSV51587978, COSV99257800; called by muse, mutect2, varscan2
- TBCCD1 | c.1512G>T p.W504C | Missense Mutation (SNP) | VAF 48/316 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100112188; called by muse, mutect2, varscan2
- TBX22 | c.551G>T p.C184F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as CM074593, COSV64787027; called by muse, varscan2
- TEKT1 | c.493C>A p.R165S | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100106519; called by muse, mutect2, varscan2
- THEMIS | c.1754C>T p.P585L | Missense Mutation (SNP) | VAF 93/399 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100965674; called by muse, mutect2, varscan2
- THSD7A | c.4808G>C p.R1603T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as COSV101349214; called by muse, mutect2
- TMEM135 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs752790111, COSV100450344; called by muse, varscan2
- TMEM44 | c.991A>T p.R331* (on ENST00000392432 / NM_001166305.2; = p.R284* on NM_138399.5) | Nonsense Mutation (SNP) | VAF 110/531 reads (21%) | catalogued as COSV99862031; called by muse, mutect2, varscan2
- TP53 | c.456del p.G154Afs*16 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | catalogued as COSV52765928, COSV52978254, COSV53086786; called by mutect2, varscan2
- TRAT1 | c.147C>A p.H49Q | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV99849658; called by muse, mutect2, varscan2
- TRHDE | c.1389A>T p.E463D | Missense Mutation (SNP) | VAF 51/218 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99673128; called by muse, mutect2, varscan2
- TRHDE | c.1808T>C p.L603S | Missense Mutation (SNP) | VAF 63/234 reads (27%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV99673129; called by muse, mutect2, varscan2
- TRIM24 | c.2015-2A>T p.X672_splice (on ENST00000343526 / NM_015905.3; = p.X638_splice on NM_003852.4) | Splice Site (SNP) | VAF 28/180 reads (16%) | catalogued as COSV100631385; called by muse, mutect2, varscan2
- TRIM39 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.778); catalogued as COSV100935956; called by muse, mutect2, varscan2
- TRIM55 | c.47C>G p.T16S | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.171); catalogued as COSV52543747, COSV99397331; called by muse, mutect2, varscan2
- TRPC1 | c.1766G>T p.G589V (on ENST00000476941 / NM_001251845.2; = p.G555V on NM_003304.4) | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV99859479; called by muse, mutect2, varscan2
- TRPC3 | c.376C>A p.P126T (on ENST00000379645 / NM_001366479.2; = p.P53T on NM_003305.2) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53373744, COSV99313677; called by muse, mutect2
- TSC22D2 | c.1537G>T p.V513L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs746055641, COSV100721307; called by muse, mutect2, varscan2
- TSPAN6 | c.305del p.L102Wfs*9 | Frame Shift Del (DEL) | VAF 10/16 reads (63%) | catalogued as rs757907711; called by mutect2, varscan2
- TSPOAP1 | c.4127G>A p.R1376K | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.012); catalogued as COSV99273190; called by muse, mutect2, varscan2
- TTC14 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 44/298 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99932487; called by muse, mutect2, varscan2
- TTC6 | c.547G>A p.G183R (on ENST00000267368; = p.G1549R on NM_001310135.3) | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99942430; called by muse, mutect2, varscan2
- TTN | c.68524C>A p.L22842M (on ENST00000591111; = p.L15418M on NM_003319.4) | Missense Mutation (SNP) | VAF 42/145 reads (29%) | PolyPhen benign (0.054); catalogued as COSV100635373; called by muse, mutect2, varscan2
- TTN | c.45737A>T p.Y15246F (on ENST00000591111; = p.Y7822F on NM_003319.4) | Missense Mutation (SNP) | VAF 45/190 reads (24%) | PolyPhen probably damaging (0.994); catalogued as COSV100635375, COSV59936567; called by muse, mutect2, varscan2
- TTN | c.33679C>A p.P11227T (on ENST00000591111; = p.P10300T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | PolyPhen benign (0.366); catalogued as rs1013759400, COSV100635376, COSV60168859; called by muse, mutect2, varscan2
- TTN | c.20498C>A p.P6833Q (on ENST00000591111; = p.P5906Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | PolyPhen possibly damaging (0.788); catalogued as COSV100635380; called by muse, mutect2, varscan2
- TTN | c.13145C>T p.A4382V (on ENST00000591111; = p.A4336V on NM_003319.4) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | PolyPhen possibly damaging (0.542); catalogued as COSV100635382, COSV59962725; called by muse, mutect2, varscan2
- TTN | c.11530T>A p.F3844I (on ENST00000591111; = p.F3798I on NM_003319.4) | Missense Mutation (SNP) | VAF 51/213 reads (24%) | catalogued as COSV100635385; called by muse, mutect2, varscan2
- TTN | c.8125A>G p.I2709V (on ENST00000591111; = p.I2663V on NM_003319.4) | Missense Mutation (SNP) | VAF 51/183 reads (28%) | PolyPhen benign (0.024); catalogued as COSV100635391; called by muse, mutect2, varscan2
- TXNL1 | c.99-1G>T p.X33_splice | Splice Site (SNP) | VAF 40/166 reads (24%) | catalogued as COSV54181224; called by muse, mutect2
- UBR2 | c.2374G>A p.A792T | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV100867572; called by muse, mutect2, varscan2
- UBXN4 | c.20C>G p.A7G | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99739761; called by muse, mutect2, varscan2
- UBXN7 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 62/459 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV56355942; called by muse, mutect2, varscan2
- UGT3A1 | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV99955477; called by muse, mutect2, varscan2
- UNC80 | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.01); catalogued as COSV99781461; called by muse, mutect2, varscan2
- UPP1 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761983133, COSV100080973; called by muse, mutect2, varscan2
- USF3 | c.4744C>T p.P1582S | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.121); catalogued as rs772357952, COSV100325918; called by muse, mutect2, varscan2
- USP26 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100896806; called by muse, mutect2, varscan2
- USP29 | c.1786G>T p.E596* | Nonsense Mutation (SNP) | VAF 19/70 reads (27%) | catalogued as COSV54141105, COSV99518872; called by muse, mutect2, varscan2
- VSX1 | c.501C>T p.H167= | Splice Region (SNP) | VAF 15/46 reads (33%) | catalogued as COSV100942240; called by muse, mutect2, varscan2
- VWA3B | c.2411C>G p.T804S | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV101346216; called by muse, mutect2, varscan2
- WDR49 | c.658G>A p.D220N (on ENST00000308378 / NM_001366158.1; = p.D561N on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/296 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV100394067; called by muse, mutect2, varscan2
- WNT2 | c.474T>A p.S158R | Missense Mutation (SNP) | VAF 86/206 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99626506; called by muse, mutect2, varscan2
- YIPF7 | c.518G>C p.G173A | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764598281, COSV60658616; called by muse, mutect2, varscan2
- ZAP70 | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs377195771, COSV99386063; called by muse, mutect2, varscan2
- ZIC1 | c.1022G>C p.R341P | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99292592; called by muse, mutect2, varscan2
- ZIC1 | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 22/186 reads (12%) | catalogued as COSV51559299; called by muse, varscan2
- ZIC4 | c.164C>A p.P55H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs777969725, COSV101268206; called by muse, mutect2, varscan2
- ZNF195 | c.1202A>G p.Q401R (on ENST00000399602 / NM_001130520.3; = p.Q329R on NM_007152.5) | Missense Mutation (SNP) | VAF 89/341 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.895); catalogued as COSV99138555; called by muse, mutect2, varscan2
- ZNF382 | c.1549G>T p.E517* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as COSV99498188; called by muse, mutect2, varscan2
- ZNF385B | c.276C>G p.S92R | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.361); catalogued as COSV101343237; called by muse, varscan2
- ZNF385D | c.451G>T p.G151W | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV99875780, COSV99876754; called by muse, mutect2, varscan2
- ZNF440 | c.388G>T p.G130* | Nonsense Mutation (SNP) | VAF 82/334 reads (25%) | catalogued as COSV100407787; called by muse, mutect2
- ZNF440 | c.389G>C p.G130A | Missense Mutation (SNP) | VAF 82/328 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.523); catalogued as COSV100407788; called by muse, mutect2
- ZNF443 | c.901A>T p.R301* | Nonsense Mutation (SNP) | VAF 69/296 reads (23%) | catalogued as COSV100042446; called by muse, mutect2, varscan2
- ZNF451 | c.1918C>T p.H640Y | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV100675179; called by muse, varscan2
- ZNF460 | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100828149; called by muse, mutect2, varscan2
- ZNF609 | c.2876C>T p.S959L | Missense Mutation (SNP) | VAF 57/218 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs1435974587, COSV100442018; called by muse, mutect2, varscan2
- ZNF610 | c.742G>T p.V248L | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100017124; called by muse, mutect2, varscan2
- ZNF668 | c.1312G>T p.V438L | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.009); catalogued as COSV100337010, COSV56213441; called by muse, mutect2, varscan2
- ZNF676 | c.1558A>G p.T520A (on ENST00000650058; = p.T488A on NM_001001411.3) | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.122); catalogued as COSV101236379; called by muse, mutect2, varscan2
- ZNF676 | c.1358A>C p.Y453S (on ENST00000650058; = p.Y421S on NM_001001411.3) | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101236380; called by muse, varscan2
- ZNF677 | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 23/115 reads (20%) | catalogued as rs1413722272, COSV100448242; called by muse, mutect2, varscan2
- ZNF80 | c.488G>T p.C163F | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100352201, COSV57362103; called by muse, mutect2, varscan2
- ZNF804B | c.1429C>A p.P477T | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60852457; called by muse, mutect2, varscan2
- CEP70 | c.216del p.L72Ffs*12 | Frame Shift Del (DEL) | VAF 8/85 reads (9%) | called by mutect2, pindel
- GZF1 | c.1229del p.G410Afs*7 | Frame Shift Del (DEL) | VAF 20/88 reads (23%) | called by mutect2, pindel, varscan2
- IGHA2 | c.161C>A p.P54Q | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGHV1-18 | c.328A>T p.T110S | Missense Mutation (SNP) | VAF 80/376 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- IGHV1-18 | c.327C>A p.D109E | Missense Mutation (SNP) | VAF 80/374 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.88G>T p.V30L | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- IGHV3-53 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 47/492 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); called by muse, mutect2
- IGHV3-66 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- IGHV4-28 | c.161G>C p.W54S | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- IGKV1-9 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 76/257 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IZUMO2 | c.157_158del p.A53Rfs*46 | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | called by pindel, varscan2
- MLLT6 | c.936dup p.K313Efs*42 | Frame Shift Ins (INS) | VAF 11/40 reads (28%) | called by mutect2, pindel, varscan2
- OGDH | c.1848_1849del p.I617Rfs*5 | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | called by pindel, varscan2
- OR4K14 | c.737dup p.M246Ifs*20 | Frame Shift Ins (INS) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- PLSCR5 | c.624del p.I209Lfs*18 | Frame Shift Del (DEL) | VAF 20/152 reads (13%) | called by mutect2, pindel, varscan2
- PLXNB3 | c.1364del p.G455Afs*7 | Frame Shift Del (DEL) | VAF 25/51 reads (49%) | called by mutect2, pindel, varscan2
- RPL12 | c.393_394del p.E131Dfs*11 | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | called by pindel, varscan2
- SLC12A2 | c.2918_2920del p.I973del | In Frame Del (DEL) | VAF 12/50 reads (24%) | called by pindel, varscan2
- STAG1 | c.1031G>T p.G344V | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- TRAV12-2 | c.120del p.S41Lfs*27 | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | called by mutect2, pindel, varscan2
- TRAV17 | c.248T>A p.V83D | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- TULP4 | c.1687_1688del p.S563Pfs*25 | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | called by pindel, varscan2
- ZBED9 | c.3780dup p.A1261Cfs*2 | Frame Shift Ins (INS) | VAF 18/101 reads (18%) | called by mutect2, pindel, varscan2
- ABCB5 | c.2547C>T p.A849= (on ENST00000404938 / NM_001163941.2; = p.A404= on NM_178559.6) | Silent (SNP) | VAF 34/130 reads (26%) | catalogued as rs779959892, COSV51718514, COSV99329110; called by muse, mutect2, varscan2
- AGAP2 | c.1869C>A p.L623= (on ENST00000547588 / NM_001122772.2; = p.L287= on NM_014770.4) | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99224544; called by muse, mutect2
- AK8 | c.1188A>T p.P396= | Silent (SNP) | VAF 38/161 reads (24%) | catalogued as COSV100050650; called by muse, mutect2, varscan2
- ALKAL1 | c.387C>G p.T129= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100660300; called by muse, mutect2, varscan2
- ANKRD44 | c.1644G>T p.L548= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99986234; called by muse, mutect2, varscan2
- ANO5 | c.2181A>T p.I727= | Silent (SNP) | VAF 46/205 reads (22%) | catalogued as COSV100202368; called by muse, mutect2, varscan2
- APOH | c.57A>T p.A19= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99236013; called by muse, mutect2, varscan2
- B3GNT5 | c.219C>T p.Y73= | Silent (SNP) | VAF 39/206 reads (19%) | catalogued as COSV100194235; called by muse, mutect2, varscan2
- CACNA1E | c.2061C>A p.T687= | Silent (SNP) | VAF 43/191 reads (23%) | catalogued as COSV62386066; called by muse, mutect2, varscan2
- CAP2 | c.654A>G p.T218= | Silent (SNP) | VAF 65/287 reads (23%) | catalogued as COSV100012929; called by muse, mutect2, varscan2
- CCN2 | c.501C>T p.D167= | Silent (SNP) | VAF 54/225 reads (24%) | catalogued as rs139453995; called by muse, mutect2, varscan2
- CCPG1 | c.384A>G p.A128= | Silent (SNP) | VAF 48/167 reads (29%) | catalogued as COSV100197563; called by muse, mutect2, varscan2
- CD53 | c.153G>T p.T51= | Silent (SNP) | VAF 40/151 reads (26%) | catalogued as rs745562046, COSV99602426; called by muse, mutect2, varscan2
- CFHR4 | c.105T>C p.Y35= (on ENST00000367416 / NM_001201551.2; = p.Y36= on NM_006684.5) | Silent (SNP) | VAF 84/284 reads (30%) | catalogued as COSV99261563; called by muse, mutect2, varscan2
- CLIC3 | c.165C>T p.D55= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV100860486; called by muse, mutect2, varscan2
- CLSTN2 | c.2293C>A p.R765= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV101515826; called by muse, mutect2, varscan2
- CNTN5 | c.720G>T p.A240= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV54288611, COSV99682538; called by muse, mutect2, varscan2
- COL5A1 | c.1971G>C p.P657= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as COSV100880712, COSV65664820; called by muse, mutect2, varscan2
- COL6A3 | c.1206C>A p.V402= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99802347; called by mutect2, varscan2
- CPAMD8 | c.4377C>A p.G1459= (on ENST00000651564; = p.G1412= on NM_015692.5) | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV101488638; called by muse, mutect2
- CPAMD8 | c.3201C>T p.P1067= (on ENST00000651564; = p.P1020= on NM_015692.5) | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs373988558, COSV101488346; called by muse, mutect2, varscan2
- CYP4F8 | c.1143G>T p.L381= | Silent (SNP) | VAF 37/174 reads (21%) | catalogued as rs1274027899, COSV100358284; called by muse, mutect2, varscan2
- DLGAP4 | c.2748C>A p.P916= (on ENST00000339266 / NM_001365621.1; = p.P913= on NM_014902.6) | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as COSV100211698; called by muse, mutect2, varscan2
- DLX5 | c.594C>T p.N198= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as COSV99756752; called by muse, mutect2, varscan2
- DNAH3 | c.5496C>T p.F1832= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs1393878746, COSV99771362; called by muse, mutect2, varscan2
- DNAH5 | c.13774C>A p.R4592= | Silent (SNP) | VAF 16/110 reads (15%) | catalogued as COSV54210253, COSV54253592, COSV99455552; called by muse, mutect2, varscan2
- DNAH8 | c.1887G>A p.L629= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV100547465; called by muse, mutect2, varscan2
- DNAJC10 | c.658A>C p.R220= | Silent (SNP) | VAF 31/152 reads (20%) | catalogued as COSV99899692; called by muse, mutect2, varscan2
- DUXA | c.454C>A p.R152= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV101617164, COSV73729528; called by muse, mutect2, varscan2
- ENPEP | c.126G>A p.S42= | Silent (SNP) | VAF 12/206 reads (6%) | catalogued as COSV54455816; called by muse, mutect2
- F2RL3 | c.1089C>G p.T363= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV50186504; called by mutect2, varscan2
- FNDC3B | c.1329G>T p.P443= | Silent (SNP) | VAF 31/205 reads (15%) | catalogued as COSV100395188; called by muse, mutect2, varscan2
- FOXO3 | c.1824C>T p.P608= | Silent (SNP) | VAF 29/204 reads (14%) | catalogued as COSV100670294; called by muse, mutect2, varscan2
- GFM2 | c.2301T>C p.D767= | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as COSV99714793; called by muse, mutect2, varscan2
- GPR155 | c.1515C>T p.H505= | Silent (SNP) | VAF 48/194 reads (25%) | catalogued as rs1418994171, COSV99790302; called by muse, mutect2, varscan2
- GPR45 | c.852C>T p.S284= | Silent (SNP) | VAF 79/342 reads (23%) | catalogued as rs1408619721, COSV99307302; called by muse, mutect2, varscan2
- HBE1 | c.276G>T p.L92= | Silent (SNP) | VAF 36/194 reads (19%) | catalogued as COSV99496441; called by muse, mutect2, varscan2
- HBP1 | c.297A>G p.P99= | Silent (SNP) | VAF 52/124 reads (42%) | catalogued as rs999852061, COSV99753696; called by muse, mutect2, varscan2
- HCN4 | c.672C>T p.P224= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as rs1397357546, COSV99984382; called by muse, mutect2, varscan2
- HSD17B2 | c.948G>A p.K316= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as COSV52276165; called by muse, mutect2, varscan2
- IFT80 | c.864T>C p.C288= | Silent (SNP) | VAF 49/202 reads (24%) | catalogued as COSV100425213; called by muse, mutect2, varscan2
- IGHG4 | c.210C>G p.T70= | Silent (SNP) | VAF 24/142 reads (17%) | catalogued as rs746797790; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.87G>A p.E29= | Silent (SNP) | VAF 22/97 reads (23%) | called by muse, mutect2, varscan2
- IGKV3-15 | c.193A>C p.R65= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as rs775058846; called by muse, mutect2, varscan2
- IL12A | c.405G>A p.E135= | Silent (SNP) | VAF 12/125 reads (10%) | catalogued as COSV99975898; called by muse, mutect2
- IL1RAPL1 | c.423A>T p.G141= | Silent (SNP) | VAF 37/65 reads (57%) | catalogued as COSV100151650; called by muse, mutect2, varscan2
- IL36B | c.36T>C p.Y12= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV99383263; called by muse, mutect2, varscan2
- INSYN2A | c.489C>G p.G163= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV99733650; called by muse, mutect2, varscan2
- IQCG | c.441G>A p.Q147= | Silent (SNP) | VAF 129/836 reads (15%) | catalogued as COSV99502825; called by muse, mutect2, varscan2
- IRX1 | c.1191C>T p.P397= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs950004076, COSV100116877, COSV57362991; called by muse, mutect2, varscan2
- KCNA4 | c.795C>A p.A265= | Silent (SNP) | VAF 42/155 reads (27%) | catalogued as COSV100069342, COSV60253725; called by muse, mutect2, varscan2
- KLF7 | c.135G>C p.T45= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs770650535, COSV100519495, COSV58744475; called by muse, mutect2, varscan2
- L1CAM | c.1359G>T p.A453= | Silent (SNP) | VAF 56/114 reads (49%) | catalogued as COSV100649540, COSV62828990; called by muse, mutect2, varscan2
- LMTK2 | c.2670T>C p.S890= | Silent (SNP) | VAF 52/104 reads (50%) | catalogued as COSV99808043; called by muse, mutect2, varscan2
- LPO | c.1731G>A p.Q577= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as rs774847591, COSV99229553; called by muse, mutect2, varscan2
- LRP1B | c.10743G>T p.G3581= | Silent (SNP) | VAF 52/262 reads (20%) | catalogued as COSV101262170; called by muse, mutect2, varscan2
- LRP2 | c.1266T>C p.N422= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as COSV99790767; called by muse, mutect2, varscan2
- LRP2BP | c.339G>A p.G113= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as rs759075930, COSV100146076; called by muse, mutect2, varscan2
- MAGEB1 | c.624C>A p.I208= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100975146; called by muse, mutect2
- MAGEC1 | c.1119C>A p.L373= | Silent (SNP) | VAF 94/206 reads (46%) | catalogued as COSV99596825; called by muse, mutect2, varscan2
- MAP1LC3C | c.273C>T p.N91= | Silent (SNP) | VAF 44/189 reads (23%) | catalogued as COSV100606588; called by muse, mutect2, varscan2
- MAP2K5 | c.261C>T p.S87= | Silent (SNP) | VAF 45/196 reads (23%) | catalogued as COSV99462665; called by muse, mutect2, varscan2
- MDN1 | c.10293G>A p.R3431= | Silent (SNP) | VAF 38/151 reads (25%) | catalogued as COSV101021942; called by muse, varscan2
- MUC17 | c.954G>T p.T318= | Silent (SNP) | VAF 79/459 reads (17%) | catalogued as rs775661782, COSV60285545; called by muse, mutect2, varscan2
- MUC5B | c.11571A>C p.P3857= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV101500944; called by muse, mutect2, varscan2
- NCLN | c.1509G>A p.E503= | Silent (SNP) | VAF 39/167 reads (23%) | catalogued as COSV99860174; called by muse, mutect2, varscan2
- NEXMIF | c.942T>C p.Y314= | Silent (SNP) | VAF 50/104 reads (48%) | catalogued as COSV99282245; called by muse, mutect2, varscan2
- NOS3 | c.996C>A p.A332= | Silent (SNP) | VAF 139/270 reads (51%) | catalogued as COSV99872340; called by muse, mutect2, varscan2
- NPPB | c.30G>T p.A10= | Silent (SNP) | VAF 40/111 reads (36%) | catalogued as COSV100916126; called by muse, mutect2, varscan2
- NR5A2 | c.1029G>T p.G343= (on ENST00000367362 / NM_205860.3; = p.G297= on NM_003822.5) | Silent (SNP) | VAF 46/189 reads (24%) | catalogued as rs1392735185, COSV99371826; called by muse, mutect2, varscan2
- OPRK1 | c.963C>A p.T321= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV55569403, COSV99653862; called by muse, mutect2, varscan2
- OR10AG1 | c.42C>T p.L14= | Silent (SNP) | VAF 5/95 reads (5%) | catalogued as COSV100400253; called by muse, mutect2
- OR51M1 | c.384C>T p.L128= | Silent (SNP) | VAF 88/424 reads (21%) | catalogued as COSV100150437; called by muse, mutect2, varscan2
- OR56A4 | c.360C>T p.L120= | Silent (SNP) | VAF 27/136 reads (20%) | catalogued as rs1266177561, COSV58109343; called by muse, mutect2, varscan2
- OR5H14 | c.78C>A p.P26= | Silent (SNP) | VAF 183/513 reads (36%) | catalogued as COSV101454214; called by muse, mutect2, varscan2
- OR5M8 | c.777C>T p.L259= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as COSV59116064; called by muse, mutect2, varscan2
- OR6C76 | c.339C>T p.A113= | Silent (SNP) | VAF 90/372 reads (24%) | catalogued as rs772898790, COSV100094393, COSV100094403; called by muse, mutect2, varscan2
- OR8K3 | c.111C>A p.I37= | Silent (SNP) | VAF 66/191 reads (35%) | catalogued as rs1322390242, COSV100449929; called by muse, mutect2, varscan2
- PARP9 | c.2499A>G p.S833= | Silent (SNP) | VAF 35/178 reads (20%) | catalogued as COSV100831302; called by muse, mutect2, varscan2
- PCDHA11 | c.2139G>T p.T713= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100255854; called by muse, mutect2, varscan2
- PCDHA2 | c.1509G>T p.A503= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs527553477, COSV100974195, COSV65368060; called by muse, mutect2, varscan2
- PCDHA9 | c.1869C>T p.R623= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV100970209; called by muse, mutect2, varscan2
- PCLO | c.10323G>T p.V3441= | Silent (SNP) | VAF 67/159 reads (42%) | catalogued as COSV100436359, COSV100439356; called by muse, mutect2, varscan2
- PDILT | c.36C>A p.A12= | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as COSV100199892; called by muse, mutect2
- PGK2 | c.507A>G p.A169= | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as COSV100505777; called by muse, mutect2, varscan2
- PIGA | c.492G>C p.S164= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as COSV100363445, COSV100363581; called by muse, mutect2, varscan2
- PLEKHO1 | c.801C>A p.G267= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV99215472; called by muse, mutect2, varscan2
- PLXNA4 | c.144C>A p.A48= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as COSV100328014; called by muse, mutect2, varscan2
- POT1 | c.630C>T p.I210= | Silent (SNP) | VAF 68/136 reads (50%) | catalogued as rs1188736928, COSV62930424, COSV62934835; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRR11 | c.525C>A p.P175= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV99231595; called by muse, mutect2, varscan2
- PTPRO | c.42C>A p.L14= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV99842086; called by muse, mutect2
- RANBP17 | c.2970T>A p.I990= | Silent (SNP) | VAF 68/219 reads (31%) | catalogued as COSV101206423; called by muse, mutect2, varscan2
- RBMS1 | c.120C>T p.S40= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as rs767197004, COSV100817140; called by muse, mutect2, varscan2
- REXO5 | c.168T>C p.T56= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as rs547741435, COSV99759560; called by muse, mutect2, varscan2
- RINT1 | c.1113A>G p.E371= | Silent (SNP) | VAF 169/370 reads (46%) | catalogued as rs1432787565, COSV99994679; called by muse, mutect2, varscan2
- RSPO3 | c.360A>G p.L120= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as COSV100759686; called by muse, mutect2, varscan2
- SBK2 | c.375T>C p.I125= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100705297, COSV60013800; called by muse, mutect2
- SCN11A | c.3252C>A p.P1084= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV56566894, COSV56572431; called by muse, mutect2, varscan2
- SCO2 | c.336G>C p.R112= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99329886; called by muse, mutect2, varscan2
- SH3BP5 | c.882C>T p.A294= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV99508685; called by muse, mutect2, varscan2
- SIGLEC10 | c.648T>C p.H216= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs1186491949, COSV100219524; called by muse, mutect2, varscan2
- SLC14A1 | c.1038G>A p.T346= | Silent (SNP) | VAF 53/199 reads (27%) | catalogued as rs1455081495, COSV58932385; called by muse, mutect2, varscan2
- SLC30A3 | c.606G>C p.G202= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs769953328, COSV99273640; called by muse, mutect2, varscan2
- SLC36A2 | c.756C>T p.D252= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV100079517; called by muse, mutect2, varscan2
- SNPH | c.1140C>A p.T380= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100378472; called by muse, mutect2, varscan2
- TAS2R50 | c.393G>A p.V131= | Silent (SNP) | VAF 83/363 reads (23%) | catalogued as rs1399595410, COSV101115930; called by muse, mutect2, varscan2
- TBX5 | c.1155C>A p.P385= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as COSV100092445; called by muse, mutect2
- TCN1 | c.1035A>G p.T345= | Silent (SNP) | VAF 9/165 reads (5%) | catalogued as COSV99953534; called by muse, mutect2
- TDRD5 | c.900A>G p.K300= | Silent (SNP) | VAF 32/130 reads (25%) | catalogued as rs1489528606, COSV99677502; called by muse, mutect2, varscan2
- TIAM2 | c.507G>T p.L169= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV100020507; called by muse, mutect2, varscan2
- TIGD5 | c.984G>T p.L328= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100364220; called by muse, mutect2, varscan2
- TIMM50 | c.138T>C p.T46= | Silent (SNP) | VAF 31/180 reads (17%) | catalogued as rs745770811, COSV100068131; called by muse, mutect2, varscan2
- TLL1 | c.255C>A p.P85= | Silent (SNP) | VAF 52/202 reads (26%) | catalogued as COSV99288401, COSV99289555; called by muse, mutect2, varscan2
- TMEM200C | c.165C>T p.I55= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV101274877; called by muse, mutect2, varscan2
- TNR | c.1947C>T p.T649= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as COSV99692167; called by muse, mutect2, varscan2
- TPCN2 | c.576C>A p.P192= | Silent (SNP) | VAF 66/261 reads (25%) | catalogued as COSV99594068; called by muse, mutect2, varscan2
- TYK2 | c.2826G>T p.S942= | Silent (SNP) | VAF 36/177 reads (20%) | catalogued as COSV53387936, COSV99315618; called by muse, mutect2, varscan2
- USH2A | c.3750G>A p.K1250= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as rs1394170988, COSV100244169, COSV56403783; called by muse, mutect2, varscan2
- VPS4B | c.825G>A p.L275= | Silent (SNP) | VAF 49/169 reads (29%) | catalogued as COSV99448363; called by muse, mutect2, varscan2
- VSIG2 | c.918C>T p.F306= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV52517887; called by muse, mutect2
- WDFY3 | c.10134C>T p.S3378= | Silent (SNP) | VAF 45/146 reads (31%) | catalogued as COSV99886316; called by muse, mutect2, varscan2
- ZFYVE28 | c.1887C>A p.P629= | Silent (SNP) | VAF 40/117 reads (34%) | catalogued as COSV99343870; called by muse, mutect2, varscan2
- ZIC1 | c.1272C>A p.P424= | Silent (SNP) | VAF 28/211 reads (13%) | catalogued as rs368298985, COSV99292396; called by muse, varscan2
- ZNF208 | c.2412C>A p.P804= | Silent (SNP) | VAF 30/122 reads (25%) | catalogued as COSV101237266; called by muse, mutect2, varscan2
- ZNF37A | c.696A>G p.P232= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100697503; called by muse, mutect2, varscan2
- COL6A2 | c.2462-2481C>A | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as COSV56019062; called by muse, mutect2, varscan2
- CXCL12 | c.266+761G>T | Intron (SNP) | VAF 6/9 reads (67%) | catalogued as COSV100639093; called by muse, varscan2
- FAM27E5 | n.265C>A | RNA (SNP) | VAF 15/141 reads (11%) | catalogued as rs371171005; called by muse, mutect2, varscan2
- IGLL3P | n.388T>C | RNA (SNP) | VAF 18/91 reads (20%) | catalogued as rs755614601; called by muse, mutect2, varscan2
- IKBIP | c.297+7886A>G | Intron (SNP) | VAF 52/178 reads (29%) | catalogued as COSV100141734, COSV54489347; called by muse, mutect2, varscan2
- LLCFC1 | c.158-62C>T | Intron (SNP) | VAF 17/85 reads (20%) | catalogued as COSV100787353; called by muse, mutect2, varscan2
- OR2U1P | n.874C>T | RNA (SNP) | VAF 19/66 reads (29%) | called by muse, mutect2, varscan2
- PARP10 | chr8:143975239 C>T | 3'Flank (SNP) | VAF 28/81 reads (35%) | catalogued as rs782602309, COSV100478427; called by muse, mutect2, varscan2
- TTN | c.10361-4467C>A | Intron (SNP) | VAF 21/115 reads (18%) | catalogued as rs776832811, COSV100635388; called by muse, mutect2, varscan2
- TTN | c.10361-5186C>A | Intron (SNP) | VAF 44/204 reads (22%) | catalogued as COSV100621712, COSV100635389; called by muse, mutect2, varscan2
